Surgical pathology report (de-identified scan), TCGA case TCGA-IA-A40U, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Cleveland Clinic, specimen TCGA-IA-A40U-01A (Primary Tumor).

[page 1 of 3]
Results

SURGICAL

Patient Info

Patient Name

Sex

DOB

Results

Specimen #:
Submitting Physician:

FINAL DIAGNOSIS

- Left kidney, radical nephrectomy (A) - Renal cell carcinoma, papillary type (8.5 cm in greatest dimension), Fuhrman nuclear grade 3 of 4. (See comment)
- The tumor grossly extends into the renal vein and renal sinus fat.
- The renal vein margin of resection is positive for tumor.
- The ureteral, arterial and soft tissue margins of resection are negative for tumor.
- The adrenal gland is negative for tumor.
- Retro-aortic vein, biopsy (B) - Renal cell carcinoma, papillary type, invading vein wall.
- Renal vein wall, margin, biopsy (C) - Muscular wall negative for tumor. (See comment)
- IVC thrombus, excision (D) - Renal cell carcinoma, papillary type, invading vein wall.
- Para-caval lymph nodes, excision (E) - Seven lymph nodes, negative for neoplasm (0/7).
- Focal non-necrotizing granulomas. (See comment)

COMMENT

A. Procedure: Radical nephrectomy (with adrenal gland)

Specimen Laterality: Left

Tumor Site: Upper-mid pole

Tumor Size: 8.5 x 6.5 x 6.5 cm

Tumor Focality: Unifocal

Macroscopic Extent of Tumor:

- Tumor extension into renal sinus

- Tumor extension into major veins (renal vein or its segmental (muscle containing) branches, inferior vena cava)

Histologic Type: Papillary renal cell carcinoma

Sarcomatoid Features: Not identified

Tumor Necrosis: Present

Histologic Grade (Fuhrman Nuclear Grade): 3/4

Microscopic Tumor Extension: (select all that apply)

- Tumor extension into renal sinus

- Tumor extension into major vein (renal vein or its segmental (muscle containing) branches, inferior vena cava)

ICD-O-3
renal cell carcinoma, papillary
8260/3
Site: Kidney, NOS C44.9
8-3-12
ICD

[page 2 of 3]
Margins: Margin(s) involved by invasive carcinoma

- Renal vein margin

Lymphovascular Invasion: Not identified

Pathologic Findings in Nonneoplastic Kidney: Patchy subcortical chronic inflammation and focal glomerulosclerosis

Pathologic Staging (pTNM): pT3b N0 MX

Number lymph node examined: 7

Number lymph node positive: 0

C. The vein wall margin of resection is negative for tumor. A detached fragment of papillary renal cell carcinoma is present in the slides, but is not adherent to the wall.

E. A systemic granulomatous process, such as sarcoidosis, should be excluded clinically.

(Electronic Signature)

SPECIMEN SUBMITTED

A: LEFT KIDNEY

B: RETRO-AORTIC VEIN

C: WALL MARGIN

D: THROMBUS

E: PARA-CAVAL LYMPH NODES

CLINICAL DATA

LEFT RENAL MASS AND IVC THROMBUS

GROSS DESCRIPTION

A. Received in formalin labeled "left kidney" is a specimen consisting of a left kidney surrounded by an envelope of fibroadipose tissue measuring 20.5 x 9.6 x 7.0 cm and weighing 740 grams. The kidney measures 13.5 x 6.8 x 5.0 cm. The kidney demonstrates an 8.5 x 6.5 x 6.5 cm tan soft and friable mass in the upper and mid poles of the kidney. Extensive necrosis is identified. Focal hemorrhage is seen. The mass grossly involves the renal sinus fat. The overlying renal pelvis is unremarkable. The mass bulges the renal capsule however does not extend into the surrounding fibroadipose tissue. It is adjacent to the inked soft tissue line of resection. The tumor is sharply demarcated from the renal parenchyma which appears tan-white and pale. Satellite nodules of tumor are not present. Sectioning of the renal veins, particularly those draining the area of the mass does show the intravascular presence of neoplasm. The mass grossly involves the renal vein margin. An adrenal gland is present measuring 5.8 x 2.6 x 1.0 cm and is not involved by tumor. The adrenal cortex is yellow-orange and unremarkable. A 5 cm segment of ureter is present and is essentially unremarkable. Lymph nodes are not seen. Representative sections are submitted as follows: A1 ureter margin; A2 artery margin; A3 renal vein margin with mass; A4 - A5 mass with renal sinus and renal pelvis; A6 - A7 mass with soft tissue line of resection; A8 - A10 mass; A11 uninvolved kidney; A12 adrenal.

B. Received in formalin labeled "retroaortic vein" is a segment of vascular tissue measuring 3.5 cm in length and 0.9 cm in diameter. The lumen is occluded by tan soft and friable tissue. The tissue extends to

[page 3 of 3]
within 0.5 cm of one margin and is at the opposite margin. Focal hemorrhage and necrosis is identified. The tissue is firmly adhered to the interior vascular walls. Representative sections are submitted as follows: B1 involved margin; B2 opposite margin; B3 representative section.

C. Received in formalin labeled "wall margin" are three segments of tan-gray vascular wall aggregating to 1.6 x 1.4 x 0.5 cm. The wall appears unremarkable. The specimen is totally submitted in formalin in C1.

D. Received in formalin labeled "thrombus" are multiple fragments of tan-brown soft and friable tissue aggregating to 5 x 5 x 2.6 cm. A segment of vascular tissue is identified measuring 4.3 cm in length and 2.8 cm in diameter. The lumen is occluded by tan soft and friable tissue. The tissue demonstrates focal hemorrhage and necrosis. Representative sections are submitted in formalin in D1 - D3.

E. Received in formalin labeled "paracaval lymph nodes" are multiple fragments of yellow-brown fibroadipose tissue aggregating to 4.3 x 3.8 x 1.7 cm. Sectioning reveals multiple ovoid tan firm nodules resembling lymph nodes ranging in size from 0.4 to 1.7 cm. The nodules are submitted as follows: E1 four nodules; E2 three nodules; E3 two nodules.

Patient ID #: [REDACTED]

DOB: [REDACTED] Age: [REDACTED]

Date of Report: [REDACTED]

Date of Procedure: [REDACTED]

Date of Receipt: [REDACTED]

Submitted by: [REDACTED]

Location: [REDACTED]

Test performed by: [REDACTED]

Lab and Collection

SURGICAL PATHOLOGY (Order [REDACTED] on [REDACTED] - Lab and Collection Information

Result History

SURGICAL PATHOLOGY (Order [REDACTED] on [REDACTED] - Order Result History Report.

Result Information

Result Date and Time

Status

Provider Status

Final result

Reviewed

Status:

This result is currently not released to [REDACTED]

Display Full Result Report

Display Order Report

Source: NCI Genomic Data Commons file 6fe3d3bb-e0ba-4061-b11a-186096aea4fd (TCGA-IA-A40U.BA049E0E-E848-415B-ACBD-B615FCA71BE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).